Somatic mutation profile of tumor specimen TARGET-10-PASYHN-09A (aliquot TARGET-10-PASYHN-09A-01D) from TARGET case TARGET-10-PASYHN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.4 years (6,367 days).
Specimen TARGET-10-PASYHN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4fe42c0-31ab-4f7f-8b9a-220fa19f2b64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYHN-10A (Blood Derived Normal), aliquot TARGET-10-PASYHN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b38caa8-cf01-443f-8c99-9910480b65a0

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- ACAD11 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV53894292; called by muse, mutect2, varscan2
- CSMD3 | c.7676G>T p.G2559V (on ENST00000297405 / NM_001363185.1; = p.G2455V on NM_052900.3) | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158781, COSV99821688; called by muse, mutect2
- DISP3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as rs759615246, COSV53821020; called by muse, mutect2, varscan2
- KLHL10 | c.1825T>C p.*609Rext*6 | Nonstop Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53172735; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- RNASEL | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV62376358; called by muse, mutect2, varscan2
- USP7 | c.1018_1019insT p.R340Lfs*3 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as COSV100784179, COSV61213366, COSV61214171; called by pindel, varscan2
- NMU | c.361-1G>A p.X121_splice | Splice Site (SNP) | VAF 30/63 reads (48%) | called by muse, varscan2
- TRBJ2-7 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- ADPGK | c.948C>T p.P316= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs779778317; called by muse, varscan2
- FRMPD1 | c.4728G>T p.T1576= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV100899675; called by muse, mutect2, varscan2
- CEP164 | c.393+3576C>G | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- PUS7 | c.*47C>A | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- SGCA | c.983+972G>A | Intron (SNP) | VAF 41/100 reads (41%) | catalogued as rs765396981; called by muse, mutect2, varscan2
